Somatic mutation profile of tumor specimen TCGA-L9-A743-01A (aliquot TCGA-L9-A743-01A-43D-A397-08) from TCGA case TCGA-L9-A743, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.9 years (20,780 days).
Specimen TCGA-L9-A743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ef89e1c-653a-4be0-a6a3-b427f2dd2d00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L9-A743-10A (Blood Derived Normal), aliquot TCGA-L9-A743-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b20d50c-f569-4703-93ec-584c267e3fdf

The open-access MAF lists 122 somatic variants for this specimen: 90 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 29, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LEF1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs267607214, COSV99036297; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHOA | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 9/125 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV69041798; called by muse, mutect2
- TP53 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM900213, COSV52684909, COSV52740428, COSV52828352; called by muse, mutect2, varscan2
- ACSM1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV99532423; called by muse, mutect2, varscan2
- ATRNL1 | c.4127G>A p.G1376E | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370145, COSV58092217; called by muse, mutect2
- BACH1 | c.369T>A p.F123L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99727843; called by muse, mutect2, varscan2
- CD1D | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as COSV100939521; called by muse, mutect2
- CEP290 | c.3429G>T p.K1143N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769362204, COSV100467610; called by muse, mutect2, varscan2
- CNTNAP2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62140546, COSV62155747; called by muse, mutect2, varscan2
- CPNE3 | c.207T>A p.F69L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99547037; called by muse, mutect2, varscan2
- CREG1 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.161); catalogued as COSV100981873; called by muse, mutect2
- CYYR1 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100176394, COSV100177243; called by muse, mutect2, varscan2
- DAB2IP | c.874G>T p.G292C (on ENST00000408936; = p.G264C on NM_032552.3) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404498; called by muse, mutect2, varscan2
- DOCK11 | c.5782G>C p.E1928Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352689; called by muse, mutect2, varscan2
- F5 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100888832; called by muse, mutect2
- FAM135B | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV99417615; called by muse, mutect2
- FAT2 | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99941404; called by muse, mutect2
- FLG | c.2326C>A p.Q776K | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100910349; called by muse, mutect2, varscan2
- FSD1 | c.1305C>G p.F435L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55697492, COSV99696540; called by muse, mutect2, varscan2
- GHR | c.1767G>T p.E589D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV100049631; called by muse, mutect2, varscan2
- HFM1 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54035851, COSV99645148; called by muse, mutect2
- HIVEP2 | c.3605A>G p.Q1202R | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV99171410; called by muse, mutect2
- HMCN1 | c.12736G>A p.G4246S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99622918; called by muse, mutect2, varscan2
- HOXA1 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99760947; called by muse, mutect2, varscan2
- HRNR | c.2766T>A p.H922Q | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs377181397, COSV100912759; called by muse, mutect2, varscan2
- HSDL1 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99550230; called by muse, mutect2
- INO80 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV100731500; called by muse, mutect2
- IQGAP2 | c.4486G>T p.D1496Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99166636; called by muse, mutect2
- JCHAIN | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636239; called by muse, mutect2
- KCNU1 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV101298757; called by muse, mutect2, varscan2
- LAMA2 | c.2490G>C p.L830F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV101369851; called by muse, mutect2
- LARS1 | c.897G>C p.M299I (on ENST00000394434 / NM_020117.11; = p.M272I on NM_016460.3) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99198452; called by muse, mutect2
- LRRCC1 | c.1783A>G p.R595G | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100835246; called by muse, mutect2
- LRRIQ1 | c.4927G>A p.E1643K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101279275; called by muse, mutect2
- LTBP1 | c.3226C>A p.H1076N (on ENST00000404816 / NM_206943.4; = p.H750N on NM_000627.4) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV55378453, COSV99697639; called by muse, mutect2
- MANEA | c.484A>T p.S162C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721412; called by muse, mutect2, varscan2
- MUC17 | c.6330C>A p.S2110R | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100071277, COSV100073291; called by muse, mutect2
- NAP1L3 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV59076286; called by muse, mutect2
- NBAS | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV99866647; called by muse, mutect2
- NIPAL4 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV57439978, COSV99975841; called by muse, mutect2, varscan2
- NUP35 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV99717692; called by muse, mutect2
- NUP98 | c.5111G>T p.R1704L (on ENST00000359171 / NM_001365126.1; = p.R1687L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV100261384; called by muse, mutect2, varscan2
- NXPE1 | c.781C>T p.R261W (on ENST00000424269; = p.R119W on NM_152315.5) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs763352009; called by mutect2, varscan2
- OPN3 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100086931; called by muse, mutect2, varscan2
- OPRL1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.666); catalogued as rs774114608, COSV61091232; called by muse, mutect2
- OR2L3 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV100741893; called by muse, mutect2
- PCDHB11 | c.1916G>T p.R639M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1554285674, COSV100696877; called by muse, mutect2, varscan2
- PCDHGB5 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1233031581; called by muse, mutect2, varscan2
- PIK3C2B | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1406098427, COSV100914984; called by muse, mutect2
- PLCB1 | c.2956G>T p.G986C | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV100569096; called by muse, mutect2
- PLEKHH3 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99511689; called by muse, mutect2
- PLIN1 | c.1127C>G p.T376S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100261376; called by muse, mutect2
- POGLUT2 | c.947G>T p.R316I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101050746; called by muse, mutect2, varscan2
- PRG4 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100823562; called by muse, mutect2
- PRRC2C | c.8306C>T p.S2769L (on ENST00000367742; = p.S2767L on NM_015172.4) | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV100144531; called by muse, mutect2
- RBP3 | c.2153C>A p.P718H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1294879816; called by muse, mutect2, varscan2
- RIMS2 | c.995G>T p.R332L (on ENST00000666250 / NM_001348490.2; = p.R140L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51686773; called by muse, mutect2
- RRP8 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99601778; called by muse, mutect2
- RUFY3 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV99886674; called by muse, mutect2
- RUNDC3A | c.495T>A p.D165E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99835069; called by muse, mutect2, varscan2
- SCAI | c.1700A>G p.Y567C (on ENST00000336505 / NM_001144877.3; = p.Y590C on NM_173690.5) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.431); catalogued as COSV100332112; called by muse, mutect2, varscan2
- SH2D3A | c.101A>T p.D34V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837749; called by muse, mutect2, varscan2
- SLC25A12 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV99784618; called by muse, mutect2
- SLC47A2 | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99449505; called by muse, mutect2, varscan2
- SMIM8 | c.245A>C p.D82A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV99994630; called by muse, mutect2, varscan2
- SOS2 | c.3843G>T p.Q1281H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV53568438, COSV99365240; called by muse, mutect2
- SOX9 | c.1367C>A p.A456E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV99818078; called by muse, mutect2, varscan2
- TAF1L | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV99643984; called by muse, mutect2
- TAPT1 | c.1386A>T p.K462N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100460936; called by muse, mutect2
- TBX21 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs761685605, COSV99455804, COSV99455838; called by muse, mutect2, varscan2
- TET1 | c.5927C>T p.S1976F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101017486, COSV65389609, COSV65390791; called by muse, mutect2
- TFDP1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100945682; called by muse, mutect2
- THSD7A | c.1381A>T p.T461S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV101448507; called by muse, mutect2, varscan2
- TRPC5 | c.1897-2A>G p.X633_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99459075; called by muse, mutect2
- TRPC5 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.688); catalogued as COSV99459078; called by muse, mutect2, varscan2
- TTN | c.48529G>C p.E16177Q (on ENST00000591111; = p.E8753Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/137 reads (5%) | PolyPhen benign (0.189); catalogued as COSV100590602; called by muse, mutect2
- TTN | c.7090G>A p.D2364N (on ENST00000591111; = p.D2318N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV100590604; called by muse, mutect2
- USP53 | c.1958G>C p.R653T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56798201, COSV99917458; called by muse, mutect2, varscan2
- VSTM4 | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100039068; called by muse, mutect2
- WDR75 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100133957; called by muse, mutect2, varscan2
- ZFHX4 | c.7072C>A p.Q2358K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen probably damaging (0.954); catalogued as COSV99254814; called by muse, mutect2, varscan2
- ZFR2 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99506895; called by muse, mutect2
- ZNF180 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99659552; called by muse, mutect2
- ZNF558 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100037782; called by muse, mutect2, varscan2
- ZNF680 | c.94A>T p.T32S | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as COSV100548866; called by muse, mutect2
- BACH1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CCDC171 | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- GDF2 | c.909C>A p.D303E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIRREL3 | c.612del p.K204Nfs*113 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- ATF4 | c.366C>G p.L122= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as rs767181464, COSV100307495; called by muse, mutect2
- CSMD3 | c.6105T>C p.V2035= (on ENST00000297405 / NM_001363185.1; = p.V1931= on NM_052900.3) | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV99821851; called by muse, mutect2
- CUL9 | c.5106A>G p.P1702= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99334591; called by muse, mutect2, varscan2
- DNAH3 | c.1392C>T p.F464= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99764463; called by muse, mutect2
- ERAP1 | c.1917C>T p.L639= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99700565; called by muse, mutect2, varscan2
- FAM71C | c.105C>A p.G35= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100175625, COSV60943797; called by muse, mutect2, varscan2
- FLNA | c.3828T>G p.T1276= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100774233; called by muse, mutect2, varscan2
- IGHV3-20 | c.192G>T p.L64= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- KCNN2 | c.879G>A p.K293= (on ENST00000264773; = p.K505= on NM_021614.4) | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as COSV53289719, COSV99298563; called by muse, mutect2
- KRTAP23-1 | c.174A>T p.S58= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100492590; called by muse, mutect2
- MAP1A | c.4179T>A p.A1393= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1167759340, COSV100287938; called by muse, mutect2
- MUC5B | c.15336C>T p.L5112= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV101499970; called by muse, mutect2
- MYO5C | c.543C>T p.V181= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV55912019; called by muse, mutect2
- NEB | c.15294G>A p.L5098= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99413857; called by muse, mutect2
- NRP1 | c.2163C>T p.C721= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99587582; called by muse, mutect2
- OBSCN | c.22767T>A p.I7589= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100800438; called by muse, mutect2, varscan2
- OTOP2 | c.735C>T p.P245= | Silent (SNP) | VAF 12/362 reads (3%) | catalogued as rs1292021621; called by muse, mutect2
- PCDHGB2 | c.1281G>T p.G427= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99528861; called by muse, mutect2, varscan2
- PDILT | c.528C>T p.I176= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs186692475, COSV56701147; called by muse, mutect2, varscan2
- PRKG1 | c.339C>T p.I113= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100907622; called by muse, mutect2, varscan2
- SEC14L3 | c.594C>T p.F198= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1260786548, COSV53181304; called by muse, mutect2, varscan2
- SPTA1 | c.5520T>C p.A1840= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV100934068; called by muse, mutect2, varscan2
- TCP1 | c.1311G>C p.A437= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100364635; called by muse, mutect2
- TLL2 | c.858G>C p.V286= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100780085; called by muse, mutect2
- TLR7 | c.2934C>A p.L978= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV101027690, COSV66124154; called by muse, mutect2
- TRAF3IP2 | c.1098G>A p.E366= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs762591912, COSV100389572, COSV60676184; called by mutect2, varscan2
- TRAV8-4 | c.294C>A p.P98= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- WDR75 | c.1224G>T p.R408= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100133959, COSV100134395; called by muse, mutect2, varscan2
- ZNF229 | c.376C>T p.L126= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- ATP2B2 | c.*258A>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100659489; called by muse, mutect2
- CBX2 | c.288+13G>A | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as rs200711963; called by muse, mutect2
- PAQR6 | c.*267G>A | 3'UTR (SNP) | VAF 16/226 reads (7%) | catalogued as rs1267194382, COSV99430653; called by muse, mutect2
